HCMI case HCM-BROD-0118-C16 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c297718c-1d40-439a-a5de-09c5eb5ccea9

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Year of birth: 1971; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C78.2; Tissue or organ of origin: Stomach, NOS; Site of resection or biopsy: Peritoneum, NOS; Classification of tumor: metastasis; Age at diagnosis: 46.0 years (16,790 days); AJCC staging edition: 7th; Tumor grade: GX; Metastasis at diagnosis: Metastasis, NOS; Prior treatment: Yes; Sites of involvement: Ascites / Peritoneum, NOS.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Irinotecan; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 257 days; Days to treatment end: 301 days.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Trastuzumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 257 days; Days to treatment end: 301 days.
   Treatment given: Treatment type: Chemotherapy; Treatment intent type: Neoadjuvant.
   Recorded as not given: adjuvant Immunotherapy (Including Vaccines), for residual disease; neoadjuvant Radiation Therapy, NOS; Surgery, NOS, for initial diagnosis.

Follow-up (3 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Days to progression: 0 days.
- Days to follow up: 256 days; Progression or recurrence: Yes; Days to progression: 256 days.
- Follow-up contacts recording only the day: day 308, day 798.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relationship type: First Degree Relative, NOS.

Biospecimens (3 samples)
- Sample HCM-BROD-0118-C16-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
- Sample HCM-BROD-0118-C16-10B: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-0118-C16-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
